Gene-level copy-number profile of tumor specimen TCGA-D6-A6EK-01A from TCGA case TCGA-D6-A6EK, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 67.2 years (24,558 days).
Specimen TCGA-D6-A6EK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.116288cf-97c7-4db1-851a-243daf762567.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-A6EK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a54d50a7-22d3-43f4-9b2f-0a2931d0c0d5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,637; copy number 2: 51,686; copy number 4: 5,495.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-A6EK-01A-11D-A31K-01): tumor purity 0.43, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 256. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
